Somatic mutation profile of tumor specimen TCGA-86-8669-01A (aliquot TCGA-86-8669-01A-11D-2393-08) from TCGA case TCGA-86-8669, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 64.2 years (23,443 days).
Specimen TCGA-86-8669-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52aa7cf8-590e-4207-ac94-4d9b4408a877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-86-8669-10A (Blood Derived Normal), aliquot TCGA-86-8669-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42976f01-b92f-4136-b17f-17ab049bebab

The open-access MAF lists 153 somatic variants for this specimen: 113 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 37, Frame Shift Del 8, Nonsense Mutation 6, Splice Site 4, Splice Region 2, RNA 2, Intron 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs776846119, COSV59205460, COSV59217320; called by muse, mutect2, varscan2
- ACSM6 | c.882G>C p.M294I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV100498883; called by muse, mutect2, varscan2
- ACSM6 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs1564589295, COSV100498885; called by muse, mutect2, varscan2
- ADGRB3 | c.3079G>A p.G1027R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53248782; called by muse, mutect2, varscan2
- ADGRE2 | c.2376G>T p.W792C | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV100215587; called by muse, mutect2, varscan2
- ALMS1 | c.1151G>T p.R384I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs1028288515, COSV100040794; called by muse, mutect2, varscan2
- ANK1 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55879401, COSV99223536; called by muse, mutect2, varscan2
- ARHGAP5 | c.3316G>C p.D1106H | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV100564913; called by muse, mutect2, varscan2
- ARL13B | c.206T>C p.I69T | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100115059; called by muse, mutect2, varscan2
- ASXL3 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV99322809, COSV99324121; called by muse, mutect2
- B3GAT2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100016525; called by muse, mutect2
- BCAN | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1357040119, COSV61258975; called by muse, mutect2, varscan2
- BCAS3 | c.404-2A>C p.X135_splice | Splice Site (SNP) | VAF 14/190 reads (7%) | catalogued as COSV101125381; called by muse, mutect2
- CADPS | c.2396A>T p.Y799F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); catalogued as COSV99335296; called by muse, mutect2, varscan2
- CDH3 | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99867215; called by muse, mutect2, varscan2
- CDKN2AIP | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV100187514; called by muse, mutect2, varscan2
- CEACAM5 | c.470T>G p.V157G | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99703680; called by muse, mutect2, varscan2
- CEP170B | c.3138T>A p.S1046R (on ENST00000453495; = p.S975R on NM_015005.3) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV101371366; called by muse, mutect2
- COL11A1 | c.3725C>A p.P1242Q | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV62172715; called by muse, mutect2, varscan2
- COL4A2 | c.4004G>A p.G1335D | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847058; called by muse, mutect2, varscan2
- COL6A3 | c.4879A>G p.T1627A | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99795806; called by mutect2, varscan2
- CPS1 | c.3284T>C p.V1095A | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV99241488; called by muse, mutect2, varscan2
- DCTN1 | c.3451A>G p.K1151E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as COSV100720846; called by muse, mutect2, varscan2
- DDR2 | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs749040833, COSV100906113; called by muse, mutect2, varscan2
- DLGAP4 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV100210672; called by muse, mutect2
- DNAH2 | c.10445G>A p.R3482H | Missense Mutation (SNP) | VAF 82/184 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs527564511, COSV66722602; called by muse, mutect2, varscan2
- DNMT3B | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs147421711; called by muse, mutect2
- DZANK1 | c.1892G>T p.G631V (on ENST00000262547 / NM_001099407.1; = p.G438V on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52753551, COSV99361423; called by muse, mutect2, varscan2
- EFHB | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs779534510, COSV99858988; called by muse, mutect2, varscan2
- FCRL4 | c.1460A>T p.K487M | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV99619104; called by muse, mutect2, varscan2
- GPR141 | c.91G>T p.G31W | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57731234, COSV57733505; called by muse, mutect2, varscan2
- GPRASP1 | c.666T>A p.S222R | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as COSV100850880; called by muse, mutect2
- GRB10 | c.1088G>A p.C363Y (on ENST00000398812; = p.C317Y on NM_001001549.3) | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100239548; called by muse, mutect2
- GRB10 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.12); catalogued as COSV100239550; called by muse, mutect2, varscan2
- GTPBP4 | c.12C>G p.Y4* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100672278; called by muse, mutect2, varscan2
- H1-4 | c.79T>A p.S27T | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99175185; called by muse, mutect2
- H4C12 | c.53G>C p.R18P | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); catalogued as COSV100694728; called by muse, mutect2, varscan2
- HDAC9 | c.1582A>T p.R528W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV101285653; called by muse, mutect2, varscan2
- HSP90B1 | c.209G>C p.R70T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100236232, COSV55356522; called by mutect2, varscan2
- IFIT1B | c.1295A>G p.Q432R | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100879023; called by muse, mutect2, varscan2
- IFT88 | c.1220A>G p.Y407C (on ENST00000319980 / NM_001318493.2; = p.Y398C on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100179381; called by muse, mutect2, varscan2
- IMPDH2 | c.1149A>T p.T383= | Splice Region (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100454888; called by muse, mutect2, varscan2
- INTU | c.1293G>T p.L431F | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100080225; called by muse, mutect2, varscan2
- IRF2BP2 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100784211; called by muse, mutect2, varscan2
- IRF4 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs780902340, COSV101110724; called by muse, mutect2, varscan2
- IRX4 | c.849C>A p.D283E | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99180752; called by muse, mutect2
- KCNQ5 | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV100570810, COSV100571249; called by muse, mutect2, varscan2
- KCTD16 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); catalogued as COSV101568680; called by muse, mutect2
- LGALS2 | c.308T>A p.L103Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99312306; called by muse, mutect2, varscan2
- LGI2 | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs756363629, COSV101180726; called by muse, mutect2, varscan2
- LRRIQ1 | c.1055A>G p.Q352R | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV101279220; called by muse, varscan2
- LRRIQ1 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 34/116 reads (29%) | catalogued as COSV101279223, COSV67828147; called by muse, mutect2, varscan2
- LRRIQ1 | c.3688G>T p.A1230S | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV101279225, COSV67831706; called by muse, mutect2, varscan2
- MAP4K1 | c.932C>A p.P311H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.947); catalogued as COSV101204098; called by muse, mutect2, varscan2
- MFN1 | c.1413G>T p.Q471H | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV99764085; called by muse, mutect2, varscan2
- MMUT | c.2202G>T p.Q734H | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV99222118; called by muse, mutect2, varscan2
- MRPS21 | c.180C>G p.C60W | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100481614; called by muse, mutect2, varscan2
- MUC16 | c.2068T>A p.F690I | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV101197392; called by muse, mutect2, varscan2
- MYT1L | c.2434G>T p.G812C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV101218016; called by muse, mutect2, varscan2
- NBEA | c.7126A>G p.N2376D | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV100075761, COSV59777897; called by muse, mutect2, varscan2
- NF1 | c.7420G>A p.D2474N (on ENST00000358273 / NM_001042492.3; = p.D2453N on NM_000267.3) | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1405212000, COSV100645776; called by muse, mutect2, varscan2
- NPAP1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1360179271, COSV61504773; called by muse, mutect2, varscan2
- NTRK2 | c.689G>A p.W230* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as COSV99451535; called by muse, mutect2, varscan2
- NXF1 | c.1520G>T p.R507L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV53672884, COSV99585658; called by muse, mutect2, varscan2
- PCDH18 | c.2704A>T p.S902C | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV100786911; called by muse, mutect2, varscan2
- PCDHA3 | c.1870G>T p.V624L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.342); catalogued as COSV100793089, COSV63546312; called by muse, mutect2, varscan2
- PCDHA9 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs782301409, COSV65323477; called by muse, mutect2
- PCDHB14 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53391836; called by muse, mutect2, varscan2
- PCDHB4 | c.2165G>A p.G722D | Missense Mutation (SNP) | VAF 65/282 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as COSV99521747; called by muse, mutect2, varscan2
- PDE8B | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV99365910; called by muse, mutect2, varscan2
- PER3 | c.1717G>C p.D573H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1484695388, COSV100728177; called by muse, mutect2, varscan2
- PGK2 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV59164223, COSV59165748; called by muse, mutect2, varscan2
- PRODH2 | c.1376T>C p.V459A (on ENST00000301175; = p.V383A on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99995097; called by muse, mutect2, varscan2
- PSG8 | c.785G>T p.C262F | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100125912; called by muse, mutect2, varscan2
- PTPRD | c.2224G>T p.G742C | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100642506; called by muse, mutect2, varscan2
- RALYL | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101568936; called by muse, mutect2, varscan2
- SAMD9 | c.2228G>T p.G743V | Missense Mutation (SNP) | VAF 89/205 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101180104, COSV66073665; called by muse, mutect2, varscan2
- SEMA4C | c.1594C>T p.H532Y | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV100560669; called by muse, mutect2, varscan2
- SH3BP4 | c.2063A>T p.E688V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100748954; called by muse, mutect2, varscan2
- SI | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100013397; called by muse, mutect2, varscan2
- SRCAP | c.3293G>C p.R1098P | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs370202769, COSV99348920; ClinVar: likely benign; called by muse, mutect2, varscan2
- SRP54 | c.1346A>T p.N449I | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV99392330; called by muse, mutect2
- TBC1D15 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.097); catalogued as COSV100041252; called by muse, mutect2, varscan2
- TGFB2 | c.1228T>A p.S410T | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.912); catalogued as COSV100859823; called by muse, mutect2, varscan2
- THEG | c.1084T>A p.L362M | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.731); catalogued as COSV100700550; called by muse, mutect2
- TNC | c.6085C>T p.R2029C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261019634, COSV100404726; called by muse, mutect2, varscan2
- TPRKB | c.15T>G p.H5Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1181710439, COSV99721681; called by muse, mutect2, varscan2
- TRIB3 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs146704824, COSV99423553; called by muse, mutect2, varscan2
- TRPA1 | c.774C>A p.C258* | Nonsense Mutation (SNP) | VAF 25/121 reads (21%) | catalogued as COSV100082790; called by muse, mutect2, varscan2
- TTLL9 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as rs201229092, COSV100206085; called by muse, mutect2, varscan2
- TXLNG | c.1092C>G p.F364L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV66330636; called by muse, mutect2, varscan2
- TXNDC5 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs755878207, COSV101124299; called by muse, mutect2, varscan2
- VEGFC | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99709268; called by muse, mutect2, varscan2
- VRK1 | c.577-1G>C p.X193_splice | Splice Site (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99388129; called by muse, mutect2, varscan2
- WNT16 | c.820C>A p.Q274K (on ENST00000222462 / NM_057168.2; = p.Q264K on NM_016087.2) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.02); catalogued as rs753293526, COSV99742828; called by muse, mutect2, varscan2
- YTHDC2 | c.4031del p.X1344_splice | Splice Site (DEL) | VAF 9/20 reads (45%) | catalogued as COSV99362777; called by mutect2, pindel, varscan2
- ZFPM2 | c.2837G>T p.S946I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV101022910, COSV65873212; called by muse, mutect2, varscan2
- ZNF181 | c.1234A>T p.K412* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV101106148; called by muse, mutect2, varscan2
- ZNF528 | c.220A>G p.K74E | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV100846597; called by muse, mutect2, varscan2
- BACH2 | c.1761_1764del p.N588Pfs*25 | Frame Shift Del (DEL) | VAF 29/81 reads (36%) | called by mutect2, pindel, varscan2
- CD2AP | c.1547_1567delinsC p.E516Afs*12 | Frame Shift Del (DEL) | VAF 41/108 reads (38%) | called by pindel, varscan2*
- DENND4C | c.4993G>A p.V1665I (on ENST00000434457 / NM_001330640.2; = p.V1616I on NM_017925.7) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- DNMT1 | c.3994_4010del p.H1332Gfs*10 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- IKBKG | c.127_130del p.G43Kfs*9 | Frame Shift Del (DEL) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- KRT26 | c.938dup p.E314Gfs*15 | Frame Shift Ins (INS) | VAF 75/138 reads (54%) | called by mutect2, pindel, varscan2
- MARCHF2 | c.193_195del p.R65del | In Frame Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- MYH4 | c.1992del p.N665Tfs*2 | Frame Shift Del (DEL) | VAF 42/116 reads (36%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.1381C>A p.P461T | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- PSMD1 | c.2171_2175del p.V724Gfs*18 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- SFTPB | c.670_672+27del p.X224_splice | Splice Site (DEL) | VAF 22/118 reads (19%) | called by mutect2, pindel
- SMC4 | c.810del p.L270Ffs*8 | Frame Shift Del (DEL) | VAF 14/81 reads (17%) | called by mutect2, pindel, varscan2
- TP53BP1 | c.3116_3132del p.I1039Rfs*3 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | called by mutect2, pindel, varscan2
- WASHC2A | c.621A>G p.E207= | Splice Region (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- ABCC12 | c.504C>T p.A168= | Silent (SNP) | VAF 7/117 reads (6%) | catalogued as COSV60914050; called by muse, mutect2
- ADGRA3 | c.2700C>T p.Y900= | Silent (SNP) | VAF 48/192 reads (25%) | catalogued as rs377710469; called by muse, mutect2, varscan2
- AL592490.1 | c.1269C>T p.P423= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs1425163485, COSV101308057; called by muse, mutect2, varscan2
- ALPG | c.597G>A p.Q199= | Silent (SNP) | VAF 30/115 reads (26%) | catalogued as COSV54966451; called by muse, mutect2, varscan2
- ANKRD20A1 | c.2001A>T p.T667= | Silent (SNP) | VAF 20/154 reads (13%) | called by muse, varscan2
- ARHGEF40 | c.2082A>T p.V694= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100069849; called by muse, mutect2, varscan2
- ASTN1 | c.2712C>T p.D904= | Silent (SNP) | VAF 51/138 reads (37%) | catalogued as COSV100705240; called by muse, mutect2, varscan2
- CDK13 | c.1329A>C p.L443= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV99474884; called by muse, mutect2, varscan2
- COL3A1 | c.3489A>T p.P1163= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100482200; called by muse, mutect2, varscan2
- CSTF3 | c.519A>G p.Q173= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100123666; called by muse, mutect2, varscan2
- CTNNA3 | c.1659T>A p.G553= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV101044761; called by muse, mutect2, varscan2
- CTTNBP2 | c.2445C>T p.Y815= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99352688; called by muse, mutect2, varscan2
- DNAH9 | c.2625A>G p.P875= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV99303140; called by muse, mutect2
- DSCAML1 | c.2034G>T p.V678= (on ENST00000321322; = p.V618= on NM_020693.4) | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as COSV100354174; called by muse, mutect2, varscan2
- GDF9 | c.66C>T p.S22= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV99736991; called by muse, mutect2
- GRK3 | c.1095G>T p.G365= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV100150910; called by muse, mutect2, varscan2
- HADHB | c.168G>T p.V56= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV100501757; called by muse, mutect2, varscan2
- HSPH1 | c.2115G>T p.R705= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100184597; called by muse, mutect2, varscan2
- ITIH6 | c.2808C>A p.P936= | Silent (SNP) | VAF 18/25 reads (72%) | catalogued as COSV99512684; called by muse, mutect2, varscan2
- KIFC2 | c.858C>G p.A286= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV100023392; called by muse, mutect2, varscan2
- LHFPL3 | c.69C>A p.G23= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV101308047; called by muse, mutect2, varscan2
- MAGEE2 | c.801G>T p.L267= | Silent (SNP) | VAF 31/44 reads (70%) | catalogued as COSV100972972, COSV64898554; called by muse, mutect2, varscan2
- MEOX1 | c.273C>T p.S91= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV59355753; called by muse, mutect2
- MORN1 | c.1119G>A p.G373= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV101047724; called by muse, mutect2, varscan2
- OR2A4 | c.207C>T p.D69= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV100199595; called by muse, mutect2
- PCDHA11 | c.1716G>A p.A572= | Silent (SNP) | VAF 21/202 reads (10%) | catalogued as rs1365807310, COSV100246913, COSV56538789; called by muse, mutect2, varscan2
- PCDHB3 | c.666G>T p.R222= | Silent (SNP) | VAF 44/65 reads (68%) | catalogued as COSV99164079; called by muse, mutect2, varscan2
- PENK | c.507T>C p.R169= | Silent (SNP) | VAF 47/199 reads (24%) | catalogued as COSV100152082; called by muse, mutect2, varscan2
- PRKCB | c.180C>T p.F60= | Silent (SNP) | VAF 30/221 reads (14%) | catalogued as COSV100331761; called by muse, mutect2, varscan2
- PSMA8 | c.183G>A p.V61= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100378549; called by muse, mutect2, varscan2
- RAPGEF4 | c.1308C>T p.I436= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs910237560, COSV99909285; called by muse, mutect2, varscan2
- RTEL1 | c.675G>T p.P225= | Silent (SNP) | VAF 30/465 reads (6%) | catalogued as rs762854518, COSV100541397, COSV58893505; called by muse, mutect2
- SPINT1 | c.1101T>A p.A367= (on ENST00000344051 / NM_181642.3; = p.A351= on NM_003710.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100688807; called by muse, mutect2, varscan2
- TRBV27 | c.306C>A p.P102= | Silent (SNP) | VAF 4/40 reads (10%) | called by mutect2, varscan2
- TRPC7 | c.432G>A p.Q144= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100725354; called by muse, mutect2, varscan2
- VAV1 | c.1113C>T p.N371= | Silent (SNP) | VAF 15/222 reads (7%) | catalogued as COSV58386570; called by muse, mutect2
- ZNF430 | c.1632A>G p.E544= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1568594837, COSV99841477; called by muse, mutect2, varscan2
- MIR1297 | n.21C>T | RNA (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- PIK3C2B | c.934-1601A>G | Intron (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1622G>C | RNA (SNP) | VAF 39/118 reads (33%) | called by muse, mutect2, varscan2
